Somatic mutation profile of tumor specimen HCM-WCMC-0948-C67-01A (aliquot HCM-WCMC-0948-C67-01A-15D-A88H-36) from HCMI case HCM-WCMC-0948-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 84.0 years (30,697 days).
Specimen HCM-WCMC-0948-C67-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41e9b3cc-f9a3-4954-a253-7cbf69df3aaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0948-C67-11A (FFPE Scrolls), aliquot HCM-WCMC-0948-C67-11A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1391d7c-b8b4-4c6b-82d6-d9e8c8cbaf87

The open-access MAF lists 276 somatic variants for this specimen: 198 protein-altering or splice-affecting, 69 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 175, Silent 69, Nonsense Mutation 14, Frame Shift Del 8, Intron 5, RNA 2, 3'Flank 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS1 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 97/367 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs768912751; called by muse, mutect2, varscan2
- ADGRV1 | c.8743G>C p.E2915Q | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67986059; called by muse, mutect2, varscan2
- AHDC1 | c.2293G>C p.G765R | Missense Mutation (SNP) | VAF 63/306 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as COSV55938083; called by muse, mutect2
- AHNAK2 | c.3107C>T p.S1036F | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs759359031; called by muse, mutect2, varscan2
- AKAP9 | c.9272G>A p.R3091K (on ENST00000359028; = p.R3067K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV62353422; called by muse, mutect2, varscan2
- AP3D1 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.884); catalogued as COSV61430219; called by muse, mutect2, varscan2
- ARC | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs1345207161; called by muse, varscan2
- ARID1A | c.3860G>C p.R1287T | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61372673; called by muse, mutect2, varscan2
- BRINP3 | c.1867G>T p.E623* | Nonsense Mutation (SNP) | VAF 49/396 reads (12%) | catalogued as COSV100819524, COSV100819608; called by mutect2, varscan2
- BRSK1 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 37/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1359287747; called by muse, mutect2
- BTBD6 | c.1423G>T p.G475C | Missense Mutation (SNP) | VAF 118/251 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100527804; called by muse, mutect2, varscan2
- C8orf34 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 81/652 reads (12%) | catalogued as rs866337168; called by muse, mutect2, varscan2
- CCDC178 | c.2182G>C p.D728H (on ENST00000383096 / NM_001105528.3; = p.D690H on NM_198995.3) | Missense Mutation (SNP) | VAF 35/337 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV100287048; called by muse, mutect2, varscan2
- CD109 | c.4208C>T p.S1403F | Missense Mutation (SNP) | VAF 74/535 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.396); catalogued as COSV54645579; called by muse, mutect2, varscan2
- CDAN1 | c.2751C>G p.I917M | Missense Mutation (SNP) | VAF 62/321 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.179); catalogued as rs946371123, COSV100661178; called by muse, mutect2, varscan2
- CDH7 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 102/387 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV59892340; called by muse, mutect2, varscan2
- CENPO | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 39/452 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs369252068; called by muse, mutect2
- COL12A1 | c.3698C>T p.P1233L | Missense Mutation (SNP) | VAF 23/352 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV59393316; called by muse, mutect2
- COLEC12 | c.1943G>A p.R648K | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV68371922; called by muse, mutect2, varscan2
- CXCR4 | c.1040C>G p.S347* | Nonsense Mutation (SNP) | VAF 46/294 reads (16%) | catalogued as COSV99602519; called by muse, mutect2, varscan2
- DNAH11 | c.10855G>C p.E3619Q | Missense Mutation (SNP) | VAF 142/374 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.272); catalogued as COSV100180714; called by muse, mutect2, varscan2
- ENO2 | c.129C>G p.I43M | Missense Mutation (SNP) | VAF 51/341 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV50389461; called by muse, mutect2, varscan2
- EPHA5 | c.2809C>T p.R937C | Missense Mutation (SNP) | VAF 140/456 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs142359231, COSV56673676; called by muse, mutect2, varscan2
- FAM133A | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs762182826, COSV59075317; called by muse, mutect2, varscan2
- FAM151A | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56362847; called by muse, mutect2, varscan2
- GALM | c.506C>T p.T169I | Missense Mutation (SNP) | VAF 70/405 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302504360; called by muse, mutect2, varscan2
- GEN1 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 101/379 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV58056563; called by muse, mutect2, varscan2
- GHR | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 41/365 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV50119918; called by muse, mutect2, varscan2
- GOLGA1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs916066008; called by muse, mutect2
- GPS2 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 110/266 reads (41%) | catalogued as rs745671551, COSV59750274, COSV59751290; called by muse, varscan2
- HIVEP3 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 70/323 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.838); catalogued as COSV56025023; called by muse, mutect2, varscan2
- HSPA5 | c.1543G>C p.D515H | Missense Mutation (SNP) | VAF 142/339 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52335350; called by muse, mutect2, varscan2
- IQGAP1 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 34/307 reads (11%) | catalogued as COSV51588858; called by muse, mutect2, varscan2
- KCNH5 | c.1539G>C p.W513C | Missense Mutation (SNP) | VAF 130/365 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59769197; called by muse, mutect2, varscan2
- KCNJ14 | c.798C>G p.I266M | Missense Mutation (SNP) | VAF 14/482 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60737785; called by muse, mutect2
- KCNK1 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 57/485 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.902); catalogued as rs766786842; called by muse, mutect2, varscan2
- KCNK1 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 87/347 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1292374624; called by muse, mutect2, varscan2
- KDR | c.3299C>G p.S1100C | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55764136; called by muse, mutect2
- KLB | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 40/323 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1318895214; called by muse, mutect2, varscan2
- KLHL38 | c.1293_1294del p.R432Tfs*63 | Frame Shift Del (DEL) | VAF 63/475 reads (13%) | catalogued as rs1563593345; called by mutect2, varscan2
- KMT5C | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 52/446 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757750608; called by muse, mutect2, varscan2
- LARP1 | c.1830C>G p.D610E (on ENST00000518297 / NM_033551.3; = p.D533E on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/382 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs373845474; called by muse, mutect2
- MAD1L1 | c.514A>G p.S172G | Missense Mutation (SNP) | VAF 24/488 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.138); catalogued as COSV56229318; called by muse, mutect2
- MGAM | c.3290G>A p.R1097H | Missense Mutation (SNP) | VAF 44/286 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs768127980; called by muse, mutect2, varscan2
- MS4A13 | c.124A>C p.I42L | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV65446209; called by mutect2, varscan2
- MUC4 | c.12625C>T p.L4209F | Missense Mutation (SNP) | VAF 107/577 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.919); catalogued as rs1431589968; called by muse, mutect2, varscan2
- N4BP2 | c.4075G>A p.E1359K | Missense Mutation (SNP) | VAF 36/470 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.067); catalogued as rs1050247358, COSV99789102; called by muse, mutect2
- NAB2 | c.1561G>C p.E521Q | Missense Mutation (SNP) | VAF 57/305 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV55665324; called by muse, mutect2, varscan2
- NACA2 | c.381G>C p.K127N | Missense Mutation (SNP) | VAF 99/532 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV101478538; called by muse, mutect2, varscan2
- NHLH1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99042927; called by muse, mutect2, varscan2
- NOTCH3 | c.6025C>T p.R2009W | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151322770; called by muse, mutect2
- OR4Q3 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 148/1139 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV100057291; called by muse, mutect2, varscan2
- PCDHB5 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1563871451; called by muse, mutect2
- PDCL3 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 43/373 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV51809645; called by muse, mutect2, varscan2
- PDZRN4 | c.2740C>A p.R914S (on ENST00000402685 / NM_001164595.2; = p.R656S on NM_013377.4) | Missense Mutation (SNP) | VAF 52/330 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54191734; called by muse, mutect2, varscan2
- PENK | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 51/455 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs149421409; called by muse, mutect2, varscan2
- PHAX | c.1002G>A p.M334I | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV52552624; called by muse, mutect2, varscan2
- PIGN | c.488G>C p.R163T | Missense Mutation (SNP) | VAF 65/605 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs762617243; called by muse, mutect2, varscan2
- PLA2R1 | c.559C>G p.Q187E | Missense Mutation (SNP) | VAF 127/532 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1351548296; called by muse, mutect2, varscan2
- PSME4 | c.2766G>C p.K922N | Missense Mutation (SNP) | VAF 144/521 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101122630; called by muse, mutect2, varscan2
- PUS7L | c.1624G>T p.A542S | Missense Mutation (SNP) | VAF 56/576 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV61261892; called by muse, mutect2
- RAPGEF1 | c.872G>C p.R291T | Missense Mutation (SNP) | VAF 39/339 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64700141; called by muse, mutect2, varscan2
- RB1CC1 | c.992C>G p.S331C | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50242929; called by muse, mutect2
- SEC22C | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52567053, COSV52567683; called by muse, mutect2
- SEMA6D | c.1947A>C p.E649D (on ENST00000316364 / NM_153618.2; = p.E587D on NM_020858.2) | Missense Mutation (SNP) | VAF 32/382 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV60371874, COSV60373482, COSV60380284; called by muse, mutect2
- SETD1B | c.5853G>C p.K1951N | Missense Mutation (SNP) | VAF 16/321 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57350059; called by muse, mutect2
- SHANK1 | c.5942G>A p.R1981H | Missense Mutation (SNP) | VAF 77/322 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.661); catalogued as rs200050673; called by muse, mutect2, varscan2
- SLC22A7 | c.1389G>C p.Q463H (on ENST00000372585 / NM_153320.2; = p.Q461H on NM_006672.3) | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746383922; called by muse, mutect2, varscan2
- STAB1 | c.2869G>A p.G957S | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760302220, COSV58733221; called by muse, mutect2, varscan2
- STAMBP | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 72/750 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs764823816; called by muse, mutect2
- SUFU | c.734T>C p.F245S | Missense Mutation (SNP) | VAF 125/306 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1303650670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCP11 | c.826C>T p.P276S (on ENST00000512012; = p.P214S on NM_018679.5) | Missense Mutation (SNP) | VAF 34/460 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as COSV55133395; called by muse, mutect2
- TMEM132D | c.2594A>C p.K865T | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV101242707, COSV67158649; called by muse, mutect2
- TNXB | c.6772G>A p.E2258K (on ENST00000647633; = p.E2011K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as rs1434254207, COSV64478989; called by muse, mutect2, varscan2
- TP53 | c.1007del p.E336Gfs*9 | Frame Shift Del (DEL) | VAF 90/228 reads (39%) | catalogued as COSV53494581; called by mutect2, varscan2
- TP53BP2 | c.2012C>T p.S671F (on ENST00000343537 / NM_001031685.3; = p.S542F on NM_005426.2) | Missense Mutation (SNP) | VAF 128/521 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV59069206; called by muse, mutect2, varscan2
- TRIM68 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs1179755886; called by muse, mutect2, varscan2
- TTN | c.54383C>T p.A18128V (on ENST00000591111; = p.A10704V on NM_003319.4) | Missense Mutation (SNP) | VAF 46/456 reads (10%) | PolyPhen possibly damaging (0.814); catalogued as COSV59954877; called by muse, mutect2, varscan2
- TYW5 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 61/476 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs1333471562; called by muse, mutect2, varscan2
- UBTF | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.071); catalogued as rs1244701669, COSV57185041; called by muse, varscan2
- USP36 | c.3246G>C p.K1082N | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61751719, COSV61754170; called by muse, mutect2, varscan2
- ZSWIM9 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs886477598; called by muse, mutect2, varscan2
- ACACA | c.6439G>A p.D2147N | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AHDC1 | c.2106G>T p.K702N | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- AHDC1 | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHDC1 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 69/237 reads (29%) | called by muse, mutect2, varscan2
- AHNAK2 | c.6358G>A p.E2120K | Missense Mutation (SNP) | VAF 101/193 reads (52%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ANKRD36C | c.4438C>G p.Q1480E | Missense Mutation (SNP) | VAF 106/521 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ANKRD50 | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 62/386 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ARL9 | c.113_116del p.I38Nfs*47 | Frame Shift Del (DEL) | VAF 38/298 reads (13%) | called by mutect2, varscan2
- ATP10A | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 92/285 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- BAZ1A | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 44/330 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BRD1 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 23/349 reads (7%) | called by muse, mutect2
- CCDC38 | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 58/361 reads (16%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- CCT6B | c.1516C>T p.H506Y | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, varscan2
- CHML | c.1367G>C p.R456T | Missense Mutation (SNP) | VAF 78/477 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CIC | c.1682G>C p.G561A | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CR1 | c.3581C>G p.S1194C | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CSMD3 | c.5932C>G p.Q1978E (on ENST00000297405 / NM_001363185.1; = p.Q1874E on NM_052900.3) | Missense Mutation (SNP) | VAF 214/440 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- CTRC | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CYP17A1 | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 121/326 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DGKA | c.854G>A p.C285Y | Missense Mutation (SNP) | VAF 31/414 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DIS3L | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- DNAH12 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- DNAH9 | c.521C>G p.S174* | Nonsense Mutation (SNP) | VAF 158/441 reads (36%) | called by muse, mutect2, varscan2
- DNMBP | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 125/303 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUSP6 | c.584_585del p.D195Gfs*2 | Frame Shift Del (DEL) | VAF 57/405 reads (14%) | called by mutect2, varscan2
- DYNC2I1 | c.1855C>T p.Q619* | Nonsense Mutation (SNP) | VAF 42/474 reads (9%) | called by muse, mutect2
- E2F5 | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 100/632 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ENTPD3 | c.1032C>G p.F344L | Missense Mutation (SNP) | VAF 49/347 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- FAM71E1 | c.514G>A p.E172K (on ENST00000600100 / NM_001308429.2; = p.E156K on NM_138411.3) | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.6); called by muse, mutect2
- FBXO32 | c.574A>G p.N192D | Missense Mutation (SNP) | VAF 53/861 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- FNDC1 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 54/397 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FSIP2 | c.9096G>C p.Q3032H | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLMP | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 98/358 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GLYATL2 | c.7G>C p.V3L | Missense Mutation (SNP) | VAF 43/333 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPR27 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- GSTM1 | c.228C>G p.I76M | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H2BC8 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HECTD2 | c.1810del p.D604Ifs*22 | Frame Shift Del (DEL) | VAF 68/195 reads (35%) | called by mutect2, varscan2
- HES6 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 73/299 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- HNRNPLL | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 72/460 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HOXB6 | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 15/356 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- HSDL2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.439); called by muse, mutect2
- HSPA12B | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, varscan2
- ICE1 | c.5135C>G p.S1712C | Missense Mutation (SNP) | VAF 141/534 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL10RB | c.56G>C p.G19A | Missense Mutation (SNP) | VAF 29/349 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2
- IL5 | c.264C>G p.F88L | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KLF2 | c.1006C>G p.L336V | Missense Mutation (SNP) | VAF 34/448 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2
- KRT8 | c.139C>G p.R47G | Missense Mutation (SNP) | VAF 53/282 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, varscan2
- LAMB2 | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 39/419 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.224); called by muse, mutect2
- LRP6 | c.2151G>T p.K717N | Missense Mutation (SNP) | VAF 63/391 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- LRRC37A | c.2347C>G p.L783V | Missense Mutation (SNP) | VAF 46/686 reads (7%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.899); called by muse, mutect2
- MALRD1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 29/322 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2
- MAP3K21 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, varscan2
- MCMDC2 | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MLLT6 | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 23/401 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); called by muse, mutect2
- MPEG1 | c.1359C>G p.F453L | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- MUC22 | c.1361C>A p.S454Y | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MYCBP2 | c.7014G>T p.M2338I (on ENST00000357337; = p.M2376I on NM_015057.5) | Missense Mutation (SNP) | VAF 119/222 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- MYH6 | c.858C>G p.I286M | Missense Mutation (SNP) | VAF 53/363 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- MYO1E | c.3037G>C p.E1013Q | Missense Mutation (SNP) | VAF 127/310 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NIPBL | c.7589C>T p.S2530L | Missense Mutation (SNP) | VAF 48/650 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- NKX1-2 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 78/265 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP9 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 61/480 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- NPEPPS | c.25T>A p.S9T | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPEPPS | c.26C>A p.S9Y | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPHS1 | c.1987G>T p.E663* | Nonsense Mutation (SNP) | VAF 105/347 reads (30%) | called by muse, mutect2, varscan2
- PCDHB9 | c.1243G>C p.A415P | Missense Mutation (SNP) | VAF 15/244 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.697); called by muse, mutect2
- PCYOX1 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 30/315 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.414); called by muse, mutect2
- PHGDH | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PHLPP2 | c.3298G>C p.E1100Q | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- PIGA | c.673_683del p.S225Cfs*16 | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | called by mutect2, varscan2
- PLK1 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PNMA2 | c.53A>G p.Q18R | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PNPO | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 99/222 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- POLD2 | c.1306A>G p.T436A | Missense Mutation (SNP) | VAF 100/525 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PPFIBP2 | c.2062C>G p.H688D | Missense Mutation (SNP) | VAF 64/401 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PRAMEF19 | c.294G>A p.W98* | Nonsense Mutation (SNP) | VAF 14/342 reads (4%) | called by muse, mutect2
- PRICKLE1 | c.998G>C p.S333T | Missense Mutation (SNP) | VAF 53/342 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRKDC | c.924del p.A311Lfs*10 | Frame Shift Del (DEL) | VAF 55/390 reads (14%) | called by mutect2, varscan2
- SCAF1 | c.837G>C p.E279D | Missense Mutation (SNP) | VAF 36/334 reads (11%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCAF8 | c.2331G>C p.Q777H | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2
- SF1 | c.394C>G p.P132A | Missense Mutation (SNP) | VAF 64/326 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHKBP1 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 46/394 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SIDT2 | c.2035C>T p.Q679* | Nonsense Mutation (SNP) | VAF 52/352 reads (15%) | called by muse, varscan2
- SLC6A11 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 49/500 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- SNRNP70 | c.450G>C p.E150D | Missense Mutation (SNP) | VAF 27/376 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SOX10 | c.651dup p.G218Rfs*63 | Frame Shift Ins (INS) | VAF 40/206 reads (19%) | called by mutect2, varscan2
- SOX10 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by mutect2, varscan2
- SPAG5 | c.1375C>G p.L459V | Missense Mutation (SNP) | VAF 40/514 reads (8%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.461); called by muse, mutect2
- SPINDOC | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPSB3 | c.776C>G p.T259R | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPTAN1 | c.4361G>C p.C1454S | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by mutect2, varscan2
- SYNE2 | c.10088G>A p.C3363Y | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TENM2 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); called by muse, mutect2
- TLN1 | c.2527G>C p.D843H | Missense Mutation (SNP) | VAF 38/445 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2
- TMEM190 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, varscan2
- TMEM62 | c.886G>C p.D296H | Missense Mutation (SNP) | VAF 122/314 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNC | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 221/454 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOP2A | c.4499T>C p.M1500T | Missense Mutation (SNP) | VAF 20/442 reads (5%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.01); called by muse, mutect2
- TRBV30 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TRIP12 | c.1229del p.G410Vfs*76 | Frame Shift Del (DEL) | VAF 28/252 reads (11%) | called by mutect2, varscan2
- TTC1 | c.677G>C p.R226T | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- UBE2J1 | c.901C>G p.L301V | Missense Mutation (SNP) | VAF 51/550 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- UBE4A | c.2589G>C p.E863D (on ENST00000252108 / NM_001204077.2; = p.E870D on NM_004788.4) | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- UGT1A1 | c.602C>G p.S201* | Nonsense Mutation (SNP) | VAF 86/481 reads (18%) | called by muse, mutect2, varscan2
- USP33 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- VWA3B | c.3122T>A p.I1041N | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- WDFY4 | c.7274C>T p.S2425F | Missense Mutation (SNP) | VAF 50/354 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZCCHC3 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZKSCAN2 | c.2005A>G p.K669E | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF230 | c.1244G>A p.C415Y | Missense Mutation (SNP) | VAF 68/704 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2
- ZNF285 | c.634A>G p.N212D | Missense Mutation (SNP) | VAF 68/277 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- ZNF43 | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ZNF43 | c.1503G>C p.K501N | Missense Mutation (SNP) | VAF 116/464 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF710 | c.314T>A p.L105* | Nonsense Mutation (SNP) | VAF 27/283 reads (10%) | called by muse, mutect2
- ZNF865 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 69/278 reads (25%) | SIFT deleterious, low confidence (0.05); called by muse, mutect2, varscan2
- AC093512.2 | c.396C>G p.L132= | Silent (SNP) | VAF 76/259 reads (29%) | called by muse, mutect2, varscan2
- AHDC1 | c.1191G>C p.R397= | Silent (SNP) | VAF 40/211 reads (19%) | called by muse, mutect2, varscan2
- ATP5PF | c.174A>T p.G58= | Silent (SNP) | VAF 83/394 reads (21%) | called by muse, mutect2, varscan2
- BICDL1 | c.1680C>T p.I560= | Silent (SNP) | VAF 36/210 reads (17%) | catalogued as rs201184033, COSV57494332; called by muse, mutect2, varscan2
- CAMSAP1 | c.4452C>A p.S1484= | Silent (SNP) | VAF 38/344 reads (11%) | called by muse, varscan2
- CCDC150 | c.861G>A p.E287= | Silent (SNP) | VAF 57/500 reads (11%) | called by muse, mutect2, varscan2
- CDH9 | c.1599C>G p.L533= | Silent (SNP) | VAF 52/405 reads (13%) | catalogued as COSV50262518; called by muse, mutect2, varscan2
- CDR2L | c.724C>T p.L242= | Silent (SNP) | VAF 23/390 reads (6%) | called by muse, mutect2
- CHML | c.72A>C p.A24= | Silent (SNP) | VAF 81/584 reads (14%) | called by muse, mutect2, varscan2
- CNKSR2 | c.858G>A p.P286= | Silent (SNP) | VAF 89/331 reads (27%) | catalogued as COSV99670315; called by muse, mutect2, varscan2
- CNNM3 | c.645C>T p.R215= | Silent (SNP) | VAF 42/157 reads (27%) | catalogued as rs1221481585; called by muse, varscan2
- DACT3 | c.828C>T p.D276= | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, varscan2
- DIDO1 | c.4044C>T p.T1348= | Silent (SNP) | VAF 52/247 reads (21%) | catalogued as COSV56612710; called by muse, varscan2
- DNAH3 | c.3057G>A p.T1019= | Silent (SNP) | VAF 55/195 reads (28%) | catalogued as rs764514972; called by muse, mutect2, varscan2
- DSP | c.4899C>T p.L1633= | Silent (SNP) | VAF 99/280 reads (35%) | catalogued as rs876657459; called by muse, mutect2, varscan2
- EPHA8 | c.2223G>C p.L741= | Silent (SNP) | VAF 24/244 reads (10%) | called by muse, mutect2
- EPPK1 | c.1251C>T p.A417= | Silent (SNP) | VAF 45/216 reads (21%) | catalogued as rs782189602; called by muse, mutect2, varscan2
- FAT2 | c.5514C>T p.F1838= | Silent (SNP) | VAF 55/237 reads (23%) | catalogued as COSV99942524; called by muse, mutect2, varscan2
- FCGRT | c.255G>A p.E85= | Silent (SNP) | VAF 61/440 reads (14%) | called by muse, mutect2, varscan2
- GABRR1 | c.894G>A p.L298= | Silent (SNP) | VAF 30/310 reads (10%) | called by muse, mutect2, varscan2
- GLYR1 | c.12G>A p.V4= | Silent (SNP) | VAF 69/236 reads (29%) | catalogued as rs951333418; called by muse, mutect2, varscan2
- GPR83 | c.819C>T p.G273= | Silent (SNP) | VAF 40/302 reads (13%) | catalogued as rs771867380; called by muse, mutect2, varscan2
- H3C13 | c.63G>A p.L21= | Silent (SNP) | VAF 32/380 reads (8%) | catalogued as rs782289859; called by muse, mutect2, varscan2
- HMCN1 | c.12087C>T p.N4029= | Silent (SNP) | VAF 39/300 reads (13%) | called by muse, mutect2, varscan2
- HSD17B2 | c.117C>T p.V39= | Silent (SNP) | VAF 40/525 reads (8%) | called by muse, mutect2
- HSPA12B | c.1305G>A p.V435= | Silent (SNP) | VAF 44/234 reads (19%) | catalogued as rs1256186376; called by muse, mutect2, varscan2
- ITPRIPL2 | c.273C>T p.H91= | Silent (SNP) | VAF 91/284 reads (32%) | catalogued as rs1401585391; called by muse, mutect2, varscan2
- KRTAP3-1 | c.51C>G p.T17= | Silent (SNP) | VAF 53/712 reads (7%) | catalogued as rs1401170664; called by muse, mutect2
- LRP1 | c.11727C>T p.V3909= | Silent (SNP) | VAF 28/288 reads (10%) | called by muse, mutect2, varscan2
- MED16 | c.966C>T p.F322= | Silent (SNP) | VAF 13/212 reads (6%) | called by muse, mutect2
- MID1 | c.1389C>G p.V463= | Silent (SNP) | VAF 148/340 reads (44%) | called by muse, mutect2, varscan2
- MUC16 | c.9924G>A p.L3308= | Silent (SNP) | VAF 16/304 reads (5%) | catalogued as COSV67491621; called by muse, mutect2
- MYBPC2 | c.408C>G p.L136= | Silent (SNP) | VAF 64/237 reads (27%) | catalogued as COSV63094549; called by muse, mutect2, varscan2
- MYH7 | c.4266G>A p.Q1422= | Silent (SNP) | VAF 50/430 reads (12%) | catalogued as COSV100806027; called by muse, mutect2, varscan2
- NBEA | c.3213C>G p.L1071= | Silent (SNP) | VAF 138/433 reads (32%) | catalogued as COSV59816499; called by muse, mutect2, varscan2
- NLRP5 | c.3186G>C p.S1062= | Silent (SNP) | VAF 58/321 reads (18%) | called by muse, mutect2, varscan2
- OR5T1 | c.600T>G p.S200= | Silent (SNP) | VAF 37/591 reads (6%) | catalogued as COSV100478902, COSV57301674, COSV57301917; called by muse, mutect2
- OR8D4 | c.90C>G p.L30= | Silent (SNP) | VAF 94/448 reads (21%) | catalogued as COSV100361910; called by muse, mutect2, varscan2
- P3H1 | c.1416G>A p.V472= | Silent (SNP) | VAF 30/448 reads (7%) | catalogued as rs138050544; called by muse, mutect2
- PCDHA11 | c.1782C>T p.R594= | Silent (SNP) | VAF 58/278 reads (21%) | catalogued as rs782085408, COSV100252132; called by muse, mutect2, varscan2
- PCDHAC1 | c.57G>A p.A19= | Silent (SNP) | VAF 25/225 reads (11%) | catalogued as COSV53849789, COSV53870984; called by muse, mutect2, varscan2
- PDRG1 | c.132G>C p.L44= | Silent (SNP) | VAF 80/473 reads (17%) | catalogued as COSV52430986, COSV52431920; called by muse, mutect2, varscan2
- PGM1 | c.270G>A p.Q90= | Silent (SNP) | VAF 48/313 reads (15%) | catalogued as COSV64301038, COSV64301085; called by muse, mutect2, varscan2
- PGR | c.705G>T p.P235= | Silent (SNP) | VAF 55/349 reads (16%) | called by muse, mutect2, varscan2
- PLEC | c.7338G>A p.E2446= (on ENST00000322810 / NM_201380.4; = p.E2336= on NM_000445.5) | Silent (SNP) | VAF 17/251 reads (7%) | called by muse, mutect2
- POLRMT | c.2952C>T p.F984= | Silent (SNP) | VAF 34/265 reads (13%) | catalogued as rs992657820; called by muse, varscan2
- PRAMEF17 | c.1119G>A p.L373= | Silent (SNP) | VAF 30/218 reads (14%) | called by muse, mutect2, varscan2
- PROB1 | c.810C>T p.T270= | Silent (SNP) | VAF 65/243 reads (27%) | called by muse, mutect2, varscan2
- PTPRU | c.459C>T p.F153= | Silent (SNP) | VAF 16/161 reads (10%) | catalogued as COSV60531790, COSV60537113; called by muse, mutect2, varscan2
- RACGAP1 | c.1017G>A p.L339= | Silent (SNP) | VAF 21/202 reads (10%) | catalogued as rs774971731; called by muse, mutect2
- RAPGEF2 | c.363C>T p.D121= | Silent (SNP) | VAF 47/340 reads (14%) | called by muse, mutect2, varscan2
- RASSF5 | c.84G>A p.L28= | Silent (SNP) | VAF 41/247 reads (17%) | called by muse, mutect2, varscan2
- RTN3 | c.1383G>A p.L461= (on ENST00000377819 / NM_001265589.2; = p.L442= on NM_201428.3) | Silent (SNP) | VAF 50/373 reads (13%) | called by muse, mutect2, varscan2
- SDK2 | c.3144C>T p.S1048= | Silent (SNP) | VAF 54/385 reads (14%) | called by muse, mutect2, varscan2
- SH2B3 | c.1350C>T p.C450= | Silent (SNP) | VAF 42/354 reads (12%) | catalogued as rs772961717; called by muse, mutect2, varscan2
- SLC1A1 | c.1467C>T p.S489= | Silent (SNP) | VAF 48/367 reads (13%) | called by muse, mutect2, varscan2
- SMYD1 | c.1248C>T p.I416= | Silent (SNP) | VAF 137/483 reads (28%) | called by muse, mutect2, varscan2
- SPTBN1 | c.6G>A p.T2= | Silent (SNP) | VAF 36/385 reads (9%) | catalogued as rs202076219; called by muse, mutect2
- TAF1L | c.3651G>C p.R1217= | Silent (SNP) | VAF 232/529 reads (44%) | called by muse, mutect2
- TBC1D9B | c.1461C>T p.F487= | Silent (SNP) | VAF 21/353 reads (6%) | catalogued as rs370212987; called by muse, mutect2
- TGFBRAP1 | c.321C>T p.L107= | Silent (SNP) | VAF 100/421 reads (24%) | catalogued as rs112430410; called by muse, mutect2, varscan2
- TMPRSS2 | c.1431G>C p.V477= | Silent (SNP) | VAF 88/357 reads (25%) | called by muse, varscan2
- TP53BP2 | c.2109C>G p.L703= (on ENST00000343537 / NM_001031685.3; = p.L574= on NM_005426.2) | Silent (SNP) | VAF 90/430 reads (21%) | catalogued as COSV100636567; called by muse, mutect2, varscan2
- TPTE | c.1599G>A p.V533= (on ENST00000618007 / NM_199261.4; = p.V515= on NM_199259.4) | Silent (SNP) | VAF 104/1192 reads (9%) | called by muse, mutect2
- TRPM2 | c.3118C>T p.L1040= | Silent (SNP) | VAF 33/293 reads (11%) | called by muse, mutect2, varscan2
- USP48 | c.2997C>G p.V999= | Silent (SNP) | VAF 30/328 reads (9%) | called by muse, mutect2
- WSB1 | c.237C>G p.T79= | Silent (SNP) | VAF 18/468 reads (4%) | called by muse, mutect2
- ZBBX | c.1332A>G p.Q444= | Silent (SNP) | VAF 38/408 reads (9%) | catalogued as rs1233629359; called by muse, mutect2
- ZNF281 | c.2304G>T p.L768= | Silent (SNP) | VAF 109/474 reads (23%) | called by muse, mutect2, varscan2
- CCDC28A-AS1 | n.424A>T | RNA (SNP) | VAF 48/306 reads (16%) | called by muse, mutect2, varscan2
- CCDC28A-AS1 | n.423G>A | RNA (SNP) | VAF 48/309 reads (16%) | called by muse, mutect2, varscan2
- CUL7 | c.-216G>C | 5'UTR (SNP) | VAF 13/301 reads (4%) | called by muse, mutect2
- DLG3 | c.1820-1316A>T | Intron (SNP) | VAF 34/293 reads (12%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+5684G>T | Intron (SNP) | VAF 40/201 reads (20%) | called by muse, mutect2, varscan2
- LINC00960 | chr3:75678939 C>G | 3'Flank (SNP) | VAF 57/275 reads (21%) | called by muse, mutect2, varscan2
- MBP | c.750+176G>A | Intron (SNP) | VAF 34/274 reads (12%) | catalogued as rs778610173; called by muse, varscan2
- PEF1 | c.625+15C>T | Intron (SNP) | VAF 48/537 reads (9%) | catalogued as rs759911374; called by muse, mutect2
- SPATA13 | c.-222-25182G>C | Intron (SNP) | VAF 37/300 reads (12%) | called by muse, mutect2, varscan2
